Somatic mutation profile of tumor specimen C3L-07534-01 (aliquot CPT0412340009) from CPTAC case C3L-07534, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 48.8 years (17,836 days).
Specimen C3L-07534-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pylorus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 59c32f4d-4077-4ced-8d17-88b258adbf3b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-07534-31 (Blood Derived Normal), aliquot CPT0412490002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3e02914c-0395-41ff-871f-f27b2d614393

The open-access MAF lists 192 somatic variants for this specimen: 139 protein-altering or splice-affecting, 49 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 128, Silent 49, Nonsense Mutation 8, Frame Shift Del 2, Intron 2, Splice Site 1, 5'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KAT8 | c.292C>T p.R98W | Missense Mutation (SNP) | VAF 37/274 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54896480; called by muse, mutect2, varscan2
- AL592490.1 | c.568T>G p.F190V | Missense Mutation (SNP) | VAF 38/540 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV69425344; called by muse, mutect2
- ALPK3 | c.4213C>T p.R1405* | Nonsense Mutation (SNP) | VAF 46/440 reads (10%) | catalogued as rs1344615174, COSV51939552; called by muse, mutect2, varscan2
- ANKFN1 | c.1618G>T p.D540Y | Missense Mutation (SNP) | VAF 29/328 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59460647; called by muse, mutect2
- APCDD1 | c.145G>C p.E49Q | Missense Mutation (SNP) | VAF 28/368 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV62372523; called by muse, mutect2
- ASB5 | c.588A>C p.Q196H | Missense Mutation (SNP) | VAF 66/411 reads (16%) | SIFT tolerated (0.67); PolyPhen benign (0.037); catalogued as COSV56669600, COSV99641567; called by muse, mutect2, varscan2
- CAMK1G | c.854G>A p.R285Q | Missense Mutation (SNP) | VAF 81/360 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs778211724, COSV50521101; called by muse, mutect2, varscan2
- CAV1 | c.284C>T p.T95M | Missense Mutation (SNP) | VAF 46/546 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs372416448; called by muse, mutect2
- CCNB3 | c.3796C>T p.R1266C | Missense Mutation (SNP) | VAF 41/328 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782223489; called by muse, mutect2, varscan2
- CCT8L2 | c.1201C>A p.Q401K | Missense Mutation (SNP) | VAF 51/531 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.105); catalogued as COSV63462865; called by muse, mutect2
- CCZ1 | c.985G>A p.D329N | Missense Mutation (SNP) | VAF 28/326 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as rs1285214212; called by muse, varscan2
- DEFA5 | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 41/305 reads (13%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.616); catalogued as rs373926117; called by muse, mutect2, varscan2
- DNAH3 | c.803C>T p.T268M | Missense Mutation (SNP) | VAF 52/540 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs541602132, COSV54509013; called by muse, mutect2
- DNAJC13 | c.1006C>G p.P336A | Missense Mutation (SNP) | VAF 24/268 reads (9%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as rs968318438, CM150901; called by muse, mutect2
- DPP9 | c.932A>C p.K311T (on ENST00000598800; = p.K340T on NM_139159.5) | Missense Mutation (SNP) | VAF 28/314 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0.101); catalogued as COSV99505849; called by muse, mutect2
- EML5 | c.4682G>A p.R1561Q (on ENST00000380664; = p.R1569Q on NM_183387.3) | Missense Mutation (SNP) | VAF 33/272 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.296); catalogued as rs368772417; called by muse, mutect2, varscan2
- EPHA7 | c.169G>T p.E57* | Nonsense Mutation (SNP) | VAF 26/230 reads (11%) | catalogued as COSV65169827; called by muse, mutect2, varscan2
- EXOC3L2 | c.1942G>A p.V648M | Missense Mutation (SNP) | VAF 59/509 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.142); catalogued as rs747364981; called by muse, mutect2, varscan2
- FAM120C | c.3146G>A p.R1049H | Missense Mutation (SNP) | VAF 55/477 reads (12%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.001); catalogued as rs782576637; called by muse, mutect2, varscan2
- FAM47A | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 73/582 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs374052739, COSV60496340; called by muse, mutect2, varscan2
- FAM50A | c.343C>T p.R115W | Missense Mutation (SNP) | VAF 46/534 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1557199826; called by muse, mutect2
- FAT2 | c.10945C>T p.R3649W | Missense Mutation (SNP) | VAF 39/366 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs142359154; called by muse, mutect2, varscan2
- FAT3 | c.7216T>G p.L2406V | Missense Mutation (SNP) | VAF 41/352 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV53101747; called by muse, mutect2, varscan2
- FSTL5 | c.930G>T p.K310N | Missense Mutation (SNP) | VAF 25/227 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.342); catalogued as COSV60232379; called by muse, mutect2, varscan2
- GNAS | c.1021G>A p.G341R | Missense Mutation (SNP) | VAF 68/531 reads (13%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.005); catalogued as rs777234998, COSV58348517; called by muse, mutect2, varscan2
- IGKV3-15 | c.157T>G p.L53V | Missense Mutation (SNP) | VAF 51/538 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.076); catalogued as rs768194531; called by muse, mutect2, varscan2
- IK | c.1588C>T p.R530C | Missense Mutation (SNP) | VAF 28/252 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV64225788; called by muse, varscan2
- LRP1B | c.6731G>T p.S2244I | Missense Mutation (SNP) | VAF 30/244 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99081271; called by muse, varscan2
- MAGEA6 | c.855A>C p.K285N | Missense Mutation (SNP) | VAF 38/414 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV61449729; called by muse, mutect2
- MAGEL2 | c.1313G>A p.R438H | Missense Mutation (SNP) | VAF 97/729 reads (13%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.993); catalogued as rs1459919141; called by muse, mutect2, varscan2
- MC4R | c.662T>C p.L221P | Missense Mutation (SNP) | VAF 48/430 reads (11%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.797); catalogued as rs1485377383; called by muse, mutect2, varscan2
- NAALAD2 | c.296A>G p.K99R | Missense Mutation (SNP) | VAF 34/362 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs1199147990, COSV58961637, COSV58961852; called by muse, mutect2, varscan2
- NLRP7 | c.1090G>A p.A364T | Missense Mutation (SNP) | VAF 26/755 reads (3%) | SIFT tolerated (0.14); PolyPhen benign (0.41); catalogued as rs1416530931, COSV60182435; called by muse, mutect2
- NRXN3 | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 38/389 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.035); catalogued as rs780219523, COSV73586282; called by muse, mutect2, varscan2
- OR2W3 | c.181T>G p.F61V | Missense Mutation (SNP) | VAF 96/431 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as COSV100831867; called by muse, varscan2
- OR5H1 | c.839T>A p.V280D | Missense Mutation (SNP) | VAF 20/296 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV63403565; called by muse, mutect2
- OR5T1 | c.823A>C p.S275R | Missense Mutation (SNP) | VAF 41/403 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.248); catalogued as COSV57302939; called by muse, mutect2, varscan2
- OR5T3 | c.932A>C p.K311T | Missense Mutation (SNP) | VAF 24/332 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV57380248, COSV57381030; called by muse, mutect2
- PDZD2 | c.377A>C p.K126T | Missense Mutation (SNP) | VAF 55/456 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV56855660; called by muse, mutect2, varscan2
- PIF1 | c.116G>A p.R39H | Missense Mutation (SNP) | VAF 65/496 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as rs995321525; called by muse, mutect2, varscan2
- PKP1 | c.2086G>T p.A696S | Missense Mutation (SNP) | VAF 33/220 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55821150; called by muse, mutect2, varscan2
- PLCB3 | c.3235C>T p.Q1079* | Nonsense Mutation (SNP) | VAF 33/275 reads (12%) | catalogued as COSV99657850; called by muse, mutect2, varscan2
- PLEC | c.11152G>A p.G3718S (on ENST00000322810 / NM_201380.4; = p.G3608S on NM_000445.5) | Missense Mutation (SNP) | VAF 42/420 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs782459958; called by muse, mutect2, varscan2
- PNPLA6 | c.4084C>T p.R1362C (on ENST00000414982 / NM_001166111.2; = p.R1314C on NM_006702.5) | Missense Mutation (SNP) | VAF 30/366 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.406); catalogued as rs1204274988, CM140448; called by muse, mutect2
- PRAMEF6 | c.354A>C p.E118D | Missense Mutation (SNP) | VAF 34/526 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs756266940, COSV61910149; called by muse, mutect2
- PRDM9 | c.1570G>T p.V524F | Missense Mutation (SNP) | VAF 38/335 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as COSV99691114; called by muse, mutect2, varscan2
- PRRX1 | c.443A>C p.K148T | Missense Mutation (SNP) | VAF 62/248 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1272026144, COSV53410909, COSV99509643; called by muse, mutect2, varscan2
- SALL3 | c.2620C>T p.R874C | Missense Mutation (SNP) | VAF 60/666 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs777607456, COSV101610064; called by muse, mutect2
- SI | c.1613T>G p.L538R | Missense Mutation (SNP) | VAF 19/389 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.03); catalogued as COSV52294415; called by muse, mutect2
- SMAD2 | c.1400C>G p.S467* | Nonsense Mutation (SNP) | VAF 15/237 reads (6%) | catalogued as COSV50994800; called by muse, mutect2
- TCERG1L | c.1060C>T p.R354* | Nonsense Mutation (SNP) | VAF 33/273 reads (12%) | catalogued as rs776171772, COSV100894724; called by muse, mutect2, varscan2
- TENM3 | c.3163T>G p.L1055V | Missense Mutation (SNP) | VAF 36/337 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV69321460; called by muse, mutect2, varscan2
- TEX13C | c.2387A>G p.K796R | Missense Mutation (SNP) | VAF 68/644 reads (11%) | SIFT deleterious (0.04); catalogued as COSV66745279; called by muse, mutect2
- TMEM200A | c.1341A>C p.Q447H | Missense Mutation (SNP) | VAF 45/360 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.169); catalogued as COSV51654319, COSV51657128; called by muse, mutect2, varscan2
- TMEM94 | c.2512G>A p.V838M | Missense Mutation (SNP) | VAF 17/432 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1032687118, COSV100050151; called by muse, mutect2
- TRIML2 | c.1024A>C p.T342P | Missense Mutation (SNP) | VAF 52/490 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.891); catalogued as COSV58716205; called by muse, mutect2
- TSHZ3 | c.361G>A p.V121M | Missense Mutation (SNP) | VAF 50/444 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.402); catalogued as rs759624341; called by muse, varscan2
- TTN | c.47038C>T p.R15680C (on ENST00000591111; = p.R8256C on NM_003319.4) | Missense Mutation (SNP) | VAF 44/286 reads (15%) | PolyPhen probably damaging (0.998); catalogued as rs752764827, COSV60351055; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.9512A>G p.N3171S (on ENST00000591111; = p.N3125S on NM_003319.4) | Missense Mutation (SNP) | VAF 38/304 reads (13%) | PolyPhen probably damaging (0.994); catalogued as rs139992576; ClinVar: uncertain significance / benign; called by muse, mutect2, varscan2
- ZBBX | c.1781T>C p.L594P | Missense Mutation (SNP) | VAF 113/432 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.077); catalogued as COSV100285015, COSV56781664; called by muse, mutect2, varscan2
- ZNF804A | c.1046G>C p.S349T | Missense Mutation (SNP) | VAF 41/314 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.058); catalogued as COSV56435524; called by muse, mutect2, varscan2
- ZSCAN23 | c.1030C>T p.R344* | Nonsense Mutation (SNP) | VAF 42/390 reads (11%) | catalogued as rs771386325; called by muse, mutect2, varscan2
- ABCF3 | c.1957C>G p.L653V | Missense Mutation (SNP) | VAF 31/296 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- ADGRA1 | c.485A>G p.D162G | Missense Mutation (SNP) | VAF 29/313 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.007); called by muse, mutect2
- ANKRD30A | c.674T>G p.L225R (on ENST00000611781; = p.L169R on NM_052997.2) | Missense Mutation (SNP) | VAF 34/392 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- ARFGEF1 | c.1667G>T p.C556F | Missense Mutation (SNP) | VAF 22/249 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- ARHGAP31 | c.4102G>C p.D1368H | Missense Mutation (SNP) | VAF 38/340 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARHGEF26 | c.652C>T p.Q218* | Nonsense Mutation (SNP) | VAF 58/434 reads (13%) | called by muse, mutect2, varscan2
- ARL13A | c.404A>C p.K135T | Missense Mutation (SNP) | VAF 47/291 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- B3GALT2 | c.319C>A p.Q107K | Missense Mutation (SNP) | VAF 56/401 reads (14%) | SIFT tolerated (0.86); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- BHLHE22 | c.572G>A p.G191D | Missense Mutation (SNP) | VAF 68/579 reads (12%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- BRPF3 | c.2478C>G p.D826E | Missense Mutation (SNP) | VAF 27/212 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- BTN3A3 | c.1487A>G p.Y496C | Missense Mutation (SNP) | VAF 57/375 reads (15%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- C16orf96 | c.2874G>T p.Q958H | Missense Mutation (SNP) | VAF 33/293 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.278); called by muse, mutect2, varscan2
- CCDC105 | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 43/459 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CCDC171 | c.3904del p.H1302Mfs*3 | Frame Shift Del (DEL) | VAF 38/352 reads (11%) | called by mutect2, pindel, varscan2
- CCDC186 | c.1539A>C p.L513F | Missense Mutation (SNP) | VAF 21/140 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CCL2 | c.6A>C p.K2N | Missense Mutation (SNP) | VAF 36/289 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- CDH16 | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 51/318 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- CFH | c.549G>T p.K183N | Missense Mutation (SNP) | VAF 34/374 reads (9%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.933); called by muse, mutect2
- CNKSR3 | c.640T>G p.L214V | Missense Mutation (SNP) | VAF 24/311 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.228); called by muse, mutect2
- CNTNAP4 | c.3336A>C p.E1112D | Missense Mutation (SNP) | VAF 21/267 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.029); called by muse, mutect2
- CNTNAP4 | c.3371G>T p.R1124M | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- COX6B1 | c.109T>G p.F37V | Missense Mutation (SNP) | VAF 29/241 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- CRISPLD1 | c.963A>C p.K321N | Missense Mutation (SNP) | VAF 33/325 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2
- CSMD1 | c.3085A>T p.I1029F (on ENST00000520002; = p.I1028F on NM_033225.6) | Missense Mutation (SNP) | VAF 32/308 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CSMD3 | c.902A>T p.E301V | Missense Mutation (SNP) | VAF 22/230 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); called by muse, mutect2
- DENND1A | c.1924G>A p.G642S | Missense Mutation (SNP) | VAF 42/478 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DIAPH2 | c.2645A>G p.D882G | Missense Mutation (SNP) | VAF 32/266 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- DOCK2 | c.3637G>A p.D1213N | Missense Mutation (SNP) | VAF 24/264 reads (9%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2
- F8 | c.2003T>C p.L668P | Missense Mutation (SNP) | VAF 51/366 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAT2 | c.1118A>G p.E373G | Missense Mutation (SNP) | VAF 47/361 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GPAT3 | c.656C>A p.P219H | Missense Mutation (SNP) | VAF 32/268 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRXCR1 | c.305A>C p.K102T | Missense Mutation (SNP) | VAF 61/435 reads (14%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- IGHV1OR15-9 | c.245A>C p.K82T | Missense Mutation (SNP) | VAF 32/338 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.446); called by muse, mutect2
- IRAG2 | c.338T>G p.I113S | Missense Mutation (SNP) | VAF 43/358 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MC4R | c.129A>C p.Q43H | Missense Mutation (SNP) | VAF 45/359 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- MLLT3 | c.1338C>G p.S446R | Missense Mutation (SNP) | VAF 10/196 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.979); called by muse, mutect2
- MMP16 | c.1492T>G p.F498V | Missense Mutation (SNP) | VAF 22/189 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- MOG | c.358T>C p.S120P | Missense Mutation (SNP) | VAF 48/484 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- MYH7 | c.1379T>C p.L460P | Missense Mutation (SNP) | VAF 39/409 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MYO10 | c.1790A>G p.Q597R | Missense Mutation (SNP) | VAF 31/266 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MYO6 | c.1439T>G p.L480R | Missense Mutation (SNP) | VAF 15/209 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- NXPE2 | c.395T>G p.L132R | Missense Mutation (SNP) | VAF 50/381 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- OR10G9 | c.406A>T p.S136C | Missense Mutation (SNP) | VAF 54/332 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- OR2I1P | c.520G>T p.D174Y | Missense Mutation (SNP) | VAF 53/422 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- PIKFYVE | c.5456A>C p.K1819T | Missense Mutation (SNP) | VAF 23/303 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.42); called by muse, mutect2
- PLEKHA6 | c.724G>T p.G242* | Nonsense Mutation (SNP) | VAF 99/437 reads (23%) | called by muse, mutect2, varscan2
- PPP1R3F | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 92/690 reads (13%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PRKD1 | c.825C>G p.I275M | Missense Mutation (SNP) | VAF 52/328 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- PRKX | c.557T>G p.I186S | Missense Mutation (SNP) | VAF 54/407 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); called by muse, mutect2, varscan2
- PRR16 | c.361A>G p.N121D (on ENST00000407149 / NM_001300783.2; = p.N98D on NM_016644.2) | Missense Mutation (SNP) | VAF 43/390 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- RAB11FIP2 | c.47A>G p.Q16R | Missense Mutation (SNP) | VAF 42/395 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- RAVER1 | c.454G>C p.V152L | Missense Mutation (SNP) | VAF 55/526 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- RCAN2 | c.216A>C p.E72D | Missense Mutation (SNP) | VAF 28/219 reads (13%) | SIFT tolerated (0.59); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RIBC2 | c.127G>T p.G43W | Missense Mutation (SNP) | VAF 26/314 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- RYR3 | c.2660T>G p.L887R | Missense Mutation (SNP) | VAF 37/242 reads (15%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- SLA2 | c.133G>A p.A45T | Missense Mutation (SNP) | VAF 42/320 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- SLC8A3 | c.1697T>G p.F566C | Missense Mutation (SNP) | VAF 41/473 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); called by muse, mutect2
- SPAG17 | c.6049C>A p.L2017M | Missense Mutation (SNP) | VAF 45/293 reads (15%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPPL3 | c.643G>A p.V215I | Missense Mutation (SNP) | VAF 35/296 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SVOP | c.1303G>T p.A435S | Missense Mutation (SNP) | VAF 22/310 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); called by muse, mutect2
- SYNE1 | c.3729T>G p.N1243K (on ENST00000367255 / NM_182961.4; = p.N1250K on NM_033071.3) | Missense Mutation (SNP) | VAF 36/249 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TADA2B | c.1021G>A p.A341T | Missense Mutation (SNP) | VAF 41/348 reads (12%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- TDGF1 | c.308G>A p.G103E | Missense Mutation (SNP) | VAF 39/264 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- TEX13D | c.602C>A p.T201K | Missense Mutation (SNP) | VAF 39/293 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- TLN2 | c.4172_4175del p.Y1391Lfs*7 | Frame Shift Del (DEL) | VAF 38/384 reads (10%) | called by mutect2, pindel
- TMEM132D | c.1394A>G p.E465G | Missense Mutation (SNP) | VAF 36/420 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2
- USP29 | c.654A>C p.K218N | Missense Mutation (SNP) | VAF 30/322 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.24); called by muse, mutect2
- VCAN | c.1110A>T p.E370D | Missense Mutation (SNP) | VAF 28/334 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.25); called by muse, mutect2
- VGF | c.659G>A p.R220H | Missense Mutation (SNP) | VAF 71/558 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.869); called by muse, varscan2
- VWA8 | c.2637_2638+2del p.X879_splice | Splice Site (DEL) | VAF 47/214 reads (22%) | called by mutect2, pindel, varscan2
- ZFP36 | c.430C>A p.R144S (on ENST00000594442; = p.R138S on NM_003407.5) | Missense Mutation (SNP) | VAF 45/428 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZKSCAN7 | c.60G>T p.K20N | Missense Mutation (SNP) | VAF 29/457 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.149); called by muse, mutect2
- ZNF14 | c.451A>G p.S151G | Missense Mutation (SNP) | VAF 34/405 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.028); called by muse, mutect2
- ZNF33A | c.341C>G p.T114S (on ENST00000458705 / NM_006974.3; = p.T115S on NM_006954.2) | Missense Mutation (SNP) | VAF 29/266 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ZNF408 | c.1028C>A p.A343E | Missense Mutation (SNP) | VAF 52/375 reads (14%) | SIFT tolerated (0.53); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- ZNF610 | c.259A>C p.S87R | Missense Mutation (SNP) | VAF 30/368 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.387); called by muse, mutect2
- ZNF717 | c.1750A>C p.T584P | Missense Mutation (SNP) | VAF 36/520 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.661); called by muse, mutect2
- ADGRB3 | c.1770G>A p.L590= | Silent (SNP) | VAF 40/310 reads (13%) | catalogued as COSV65387079; called by muse, mutect2, varscan2
- ADGRG2 | c.1125T>C p.S375= (on ENST00000379869 / NM_001079858.3; = p.S372= on NM_005756.4) | Silent (SNP) | VAF 37/350 reads (11%) | called by muse, mutect2, varscan2
- APOBR | c.2913C>T p.A971= (on ENST00000431282; = p.A980= on NM_018690.4) | Silent (SNP) | VAF 79/398 reads (20%) | called by muse, mutect2, varscan2
- ATP7A | c.2418A>G p.S806= | Silent (SNP) | VAF 32/280 reads (11%) | called by muse, mutect2, varscan2
- ATRIP | c.1080C>G p.L360= | Silent (SNP) | VAF 24/215 reads (11%) | called by muse, mutect2, varscan2
- C2orf16 | c.1548G>A p.A516= | Silent (SNP) | VAF 40/322 reads (12%) | catalogued as rs201257772; called by muse, mutect2, varscan2
- CACNA2D3 | c.756T>G p.T252= | Silent (SNP) | VAF 30/288 reads (10%) | called by muse, mutect2, varscan2
- CCDC168 | c.20553C>T p.T6851= | Silent (SNP) | VAF 107/394 reads (27%) | called by muse, mutect2, varscan2
- CNTNAP4 | c.2145T>C p.S715= | Silent (SNP) | VAF 37/432 reads (9%) | catalogued as COSV56678036; called by muse, mutect2
- CRTAC1 | c.1182C>T p.P394= | Silent (SNP) | VAF 54/389 reads (14%) | catalogued as rs766490642; called by muse, mutect2, varscan2
- DOCK2 | c.3636A>G p.K1212= | Silent (SNP) | VAF 24/264 reads (9%) | called by muse, mutect2
- GAS1 | c.867C>T p.G289= | Silent (SNP) | VAF 66/553 reads (12%) | called by muse, mutect2, varscan2
- GJB1 | c.663C>A p.A221= | Silent (SNP) | VAF 69/596 reads (12%) | called by muse, mutect2, varscan2
- H2BC4 | c.348C>G p.T116= | Silent (SNP) | VAF 38/416 reads (9%) | catalogued as rs1373585365; called by muse, mutect2
- IL20RA | c.1473T>A p.I491= | Silent (SNP) | VAF 49/490 reads (10%) | called by muse, mutect2, varscan2
- IRX4 | c.882C>T p.D294= | Silent (SNP) | VAF 63/527 reads (12%) | called by muse, mutect2, varscan2
- ITIH6 | c.1449T>C p.G483= | Silent (SNP) | VAF 76/587 reads (13%) | called by muse, mutect2, varscan2
- ITPR2 | c.2076A>G p.E692= | Silent (SNP) | VAF 43/417 reads (10%) | catalogued as COSV67270863; called by muse, mutect2
- KIF7 | c.975C>T p.C325= | Silent (SNP) | VAF 52/377 reads (14%) | called by muse, mutect2, varscan2
- KLHL4 | c.1107T>G p.S369= | Silent (SNP) | VAF 52/353 reads (15%) | catalogued as COSV64139442, COSV64143670; called by muse, mutect2, varscan2
- MAGEB16 | c.477T>C p.S159= | Silent (SNP) | VAF 54/491 reads (11%) | catalogued as COSV67873939, COSV67873984; called by muse, mutect2, varscan2
- MAGI1 | c.639C>T p.G213= | Silent (SNP) | VAF 44/410 reads (11%) | catalogued as rs939265418; called by muse, mutect2, varscan2
- MPO | c.921C>T p.A307= | Silent (SNP) | VAF 42/408 reads (10%) | called by muse, mutect2
- MUC6 | c.819C>T p.T273= | Silent (SNP) | VAF 76/684 reads (11%) | called by muse, mutect2, varscan2
- NLGN4X | c.846C>T p.T282= | Silent (SNP) | VAF 30/512 reads (6%) | catalogued as rs9699286, COSV52013818; called by muse, mutect2
- NTM | c.72T>C p.L24= | Silent (SNP) | VAF 43/350 reads (12%) | called by muse, mutect2, varscan2
- NTRK3 | c.318A>G p.Q106= | Silent (SNP) | VAF 32/336 reads (10%) | called by muse, mutect2
- OR4K13 | c.426T>A p.T142= | Silent (SNP) | VAF 35/313 reads (11%) | called by muse, mutect2, varscan2
- OR5AC2 | c.507T>G p.T169= | Silent (SNP) | VAF 38/312 reads (12%) | catalogued as COSV62279496; called by muse, mutect2, varscan2
- OR5T2 | c.681T>G p.S227= | Silent (SNP) | VAF 49/429 reads (11%) | catalogued as COSV57588476, COSV57589308, COSV57590451; called by muse, mutect2, varscan2
- PCDH11X | c.3612C>G p.T1204= | Silent (SNP) | VAF 77/671 reads (11%) | called by muse, mutect2, varscan2
- PCLO | c.3132C>G p.V1044= | Silent (SNP) | VAF 83/475 reads (17%) | called by muse, mutect2, varscan2
- PRAMEF19 | c.903T>G p.T301= | Silent (SNP) | VAF 48/251 reads (19%) | called by muse, mutect2, varscan2
- PRLHR | c.123C>T p.G41= | Silent (SNP) | VAF 63/438 reads (14%) | catalogued as rs761977110; called by muse, mutect2, varscan2
- RILPL1 | c.885C>T p.T295= | Silent (SNP) | VAF 51/452 reads (11%) | called by muse, mutect2, varscan2
- RIMBP2 | c.960G>A p.P320= | Silent (SNP) | VAF 42/402 reads (10%) | catalogued as rs140021940; called by muse, mutect2, varscan2
- SAFB2 | c.1902C>T p.R634= | Silent (SNP) | VAF 31/218 reads (14%) | catalogued as rs371849776; called by muse, mutect2, varscan2
- SCN5A | c.3156C>T p.A1052= | Silent (SNP) | VAF 62/499 reads (12%) | catalogued as rs748975536, COSV100351420; ClinVar: likely benign; called by muse, mutect2, varscan2
- SCN9A | c.3807T>C p.S1269= (on ENST00000303354; = p.S1258= on NM_002977.3) | Silent (SNP) | VAF 39/171 reads (23%) | catalogued as COSV100313612; called by muse, mutect2, varscan2
- SEMA6D | c.2292A>G p.Q764= (on ENST00000316364 / NM_153618.2; = p.Q702= on NM_020858.2) | Silent (SNP) | VAF 40/363 reads (11%) | called by muse, mutect2, varscan2
- SHB | c.1239A>G p.G413= | Silent (SNP) | VAF 36/277 reads (13%) | called by muse, mutect2, varscan2
- SLC12A1 | c.300T>G p.T100= | Silent (SNP) | VAF 56/373 reads (15%) | called by muse, mutect2, varscan2
- SPAG5 | c.1401G>A p.Q467= | Silent (SNP) | VAF 38/318 reads (12%) | called by muse, mutect2, varscan2
- TCEAL5 | c.369G>T p.G123= | Silent (SNP) | VAF 68/533 reads (13%) | called by muse, mutect2, varscan2
- TSHZ3 | c.669C>T p.Y223= | Silent (SNP) | VAF 50/412 reads (12%) | catalogued as rs780383188, COSV53667135; called by muse, mutect2, varscan2
- TTN | c.93504A>G p.Q31168= (on ENST00000591111; = p.Q23744= on NM_003319.4) | Silent (SNP) | VAF 44/411 reads (11%) | catalogued as COSV100637563; called by muse, mutect2, varscan2
- USH2A | c.6102T>C p.A2034= | Silent (SNP) | VAF 78/329 reads (24%) | called by muse, mutect2, varscan2
- USP39 | c.519C>T p.Y173= | Silent (SNP) | VAF 33/388 reads (9%) | called by muse, mutect2
- WDFY4 | c.3093T>G p.G1031= | Silent (SNP) | VAF 28/262 reads (11%) | catalogued as COSV57429275; called by muse, mutect2, varscan2
- APCDD1L | chr20:58515647 G>T | 5'Flank (SNP) | VAF 33/306 reads (11%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1514+496G>C | Intron (SNP) | VAF 51/396 reads (13%) | called by muse, mutect2, varscan2
- LRRC9 | c.4277-1226A>C | Intron (SNP) | VAF 35/327 reads (11%) | called by muse, mutect2, varscan2
- ZNF559 | c.-25T>G | 5'UTR (SNP) | VAF 28/253 reads (11%) | called by muse, mutect2, varscan2
